Somatic mutation profile of tumor specimen C3L-00995-02 (aliquot CPT0169890006) from CPTAC case C3L-00995, project CPTAC-3 (Other and unspecified parts of mouth — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cheek mucosa; AJCC pathologic stage: Stage III; Tumor grade: G1; Age at diagnosis: 56.9 years (20,780 days).
Specimen C3L-00995-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Buccal Mucosa; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9bd9d254-de47-4ac9-8151-86adc189d8fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00995-31 (Blood Derived Normal), aliquot CPT0167190002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2dad064f-3e86-488e-9a9e-267a57973135

The open-access MAF lists 130 somatic variants for this specimen: 82 protein-altering or splice-affecting, 35 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 70, Silent 35, Nonsense Mutation 8, Intron 7, RNA 3, Splice Site 2, Nonstop Mutation 1, 3'Flank 1, Splice Region 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.584T>A p.I195N | Missense Mutation (SNP) | VAF 178/790 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760043106, CM092575, COSV52661172, COSV52664264, COSV52684176, COSV52720899; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ACSM4 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 82/708 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.325); catalogued as rs370415520; called by muse, mutect2, varscan2
- ADCY7 | c.1074C>G p.I358M | Missense Mutation (SNP) | VAF 14/282 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1357729002; called by muse, mutect2
- AHNAK2 | c.6722T>C p.M2241T | Missense Mutation (SNP) | VAF 54/1234 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as rs1257769081, COSV60909367; called by muse, mutect2
- ASPM | c.8050G>T p.D2684Y | Missense Mutation (SNP) | VAF 30/532 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.953); catalogued as rs1263224475, COSV54129185; called by muse, mutect2
- ASXL2 | c.3980A>G p.Y1327C | Missense Mutation (SNP) | VAF 26/346 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1413693845, COSV55470134; called by muse, mutect2
- ATP6V0A4 | c.891C>G p.I297M | Missense Mutation (SNP) | VAF 52/1178 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs372539397, COSV59472679; called by muse, mutect2
- ATRAID | c.565A>G p.I189V (on ENST00000611786; = p.I76V on NM_016085.5) | Missense Mutation (SNP) | VAF 28/321 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.318); catalogued as rs933827333; called by muse, mutect2
- C4orf54 | c.1582C>T p.R528W | Missense Mutation (SNP) | VAF 25/537 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV72766968; called by muse, mutect2
- CACHD1 | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 19/330 reads (6%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.968); catalogued as rs756542793, COSV51558766; called by muse, mutect2
- CHN2 | c.50-1G>C p.X17_splice | Splice Site (SNP) | VAF 20/308 reads (6%) | catalogued as COSV56087892; called by muse, mutect2
- CNST | c.1409C>T p.A470V | Missense Mutation (SNP) | VAF 52/536 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.024); catalogued as rs145890214; called by muse, mutect2
- COBL | c.2041G>A p.A681T | Missense Mutation (SNP) | VAF 28/410 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs778955062, COSV99474735; called by muse, mutect2
- CPNE3 | c.126G>C p.W42C | Missense Mutation (SNP) | VAF 11/204 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV52207523; called by muse, mutect2
- DDAH2 | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 17/434 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.113); catalogued as COSV65384322; called by muse, mutect2
- DDR1 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 26/542 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV100241958; called by muse, mutect2
- DNAH5 | c.6748G>A p.E2250K | Missense Mutation (SNP) | VAF 73/638 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs201285946; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EHMT2 | c.3571C>T p.R1191C | Missense Mutation (SNP) | VAF 33/632 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs1457177357; called by muse, mutect2
- GIGYF2 | c.1283-1G>C p.X428_splice | Splice Site (SNP) | VAF 19/359 reads (5%) | catalogued as COSV65254049; called by muse, mutect2
- GPR151 | c.1137G>T p.E379D | Missense Mutation (SNP) | VAF 18/386 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1353422024, COSV99695144; called by muse, mutect2
- ITPKC | c.1786G>A p.V596M | Missense Mutation (SNP) | VAF 34/375 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs751173291; called by muse, mutect2
- KANK1 | c.2963A>G p.N988S | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs769214044, COSV63215541; called by muse, mutect2, varscan2
- KLC2 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 25/714 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.075); catalogued as rs1240569511, COSV100385267, COSV57582504, COSV57583573; called by muse, mutect2
- LGALS9B | c.466C>T p.Q156* | Nonsense Mutation (SNP) | VAF 53/790 reads (7%) | catalogued as rs371715292; called by muse, mutect2
- MYH1 | c.2307C>G p.F769L | Missense Mutation (SNP) | VAF 19/494 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.982); catalogued as COSV56856480; called by muse, mutect2
- NDST2 | c.517C>T p.R173* | Nonsense Mutation (SNP) | VAF 24/386 reads (6%) | catalogued as rs1437962908; called by muse, mutect2
- NLRP6 | c.2430G>C p.Q810H | Missense Mutation (SNP) | VAF 28/426 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1428670547; called by muse, mutect2
- PALLD | c.475C>T p.Q159* | Nonsense Mutation (SNP) | VAF 34/694 reads (5%) | catalogued as COSV54975967; called by muse, mutect2
- PTPRF | c.691G>T p.A231S | Missense Mutation (SNP) | VAF 25/532 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.071); catalogued as COSV63444576; called by muse, mutect2
- RBL1 | c.2149A>G p.K717E | Missense Mutation (SNP) | VAF 9/154 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.017); catalogued as rs1002674604; called by muse, mutect2
- SCML4 | c.580C>T p.R194* | Nonsense Mutation (SNP) | VAF 13/332 reads (4%) | catalogued as COSV64637152; called by muse, mutect2
- SMO | c.2328G>A p.M776I | Missense Mutation (SNP) | VAF 13/278 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); catalogued as COSV50836817; called by muse, mutect2
- SOX6 | c.1520G>A p.R507Q (on ENST00000528429 / NM_001145819.2; = p.R480Q on NM_017508.3) | Missense Mutation (SNP) | VAF 18/291 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.489); catalogued as rs1229237263; called by muse, mutect2
- SSTR1 | c.1040C>T p.A347V | Missense Mutation (SNP) | VAF 19/494 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as COSV57457171; called by muse, mutect2
- SYTL1 | c.722C>G p.S241W (on ENST00000543823; = p.S229W on NM_032872.3) | Missense Mutation (SNP) | VAF 32/648 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100539451; called by muse, mutect2
- TBC1D1 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 32/606 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.194); catalogued as rs901968281; called by muse, mutect2
- TMEM132C | c.2383G>A p.V795I | Missense Mutation (SNP) | VAF 37/545 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as rs1052584163; called by muse, mutect2
- WDR13 | c.760G>C p.E254Q | Missense Mutation (SNP) | VAF 12/195 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.014); catalogued as rs1316601231; called by muse, mutect2
- ARHGAP1 | c.450-6C>T | Splice Region (SNP) | VAF 10/176 reads (6%) | called by muse, mutect2
- ARHGAP25 | c.133G>C p.E45Q (on ENST00000409202 / NM_001007231.3; = p.E38Q on NM_014882.3) | Missense Mutation (SNP) | VAF 46/1307 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.16); called by muse, mutect2
- ATP5F1B | c.1214C>G p.S405C | Missense Mutation (SNP) | VAF 32/761 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- B3GNT5 | c.356C>G p.S119C | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.87); called by muse, mutect2
- CALB1 | c.786G>C p.*262Yext*21 | Nonstop Mutation (SNP) | VAF 14/274 reads (5%) | called by muse, mutect2
- CARMIL2 | c.3326C>A p.S1109* | Nonsense Mutation (SNP) | VAF 17/494 reads (3%) | called by muse, mutect2
- CD207 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 14/362 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2
- CHAMP1 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 20/379 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.202); called by muse, mutect2
- CTNNA1 | c.2210A>C p.K737T | Missense Mutation (SNP) | VAF 40/383 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- ELF4 | c.60T>G p.D20E | Missense Mutation (SNP) | VAF 124/576 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- FADS1 | c.1170G>A p.W390* | Nonsense Mutation (SNP) | VAF 28/454 reads (6%) | called by muse, mutect2
- HADH | c.862C>T p.Q288* | Nonsense Mutation (SNP) | VAF 50/934 reads (5%) | called by muse, mutect2
- HNRNPDL | c.1160A>G p.Y387C | Missense Mutation (SNP) | VAF 29/241 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IL10RA | c.447G>C p.K149N | Missense Mutation (SNP) | VAF 40/582 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2
- JRKL | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 22/213 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- KRTAP10-11 | c.597C>A p.C199* | Nonsense Mutation (SNP) | VAF 48/1512 reads (3%) | called by muse, mutect2
- LDB2 | c.583G>A p.G195R | Missense Mutation (SNP) | VAF 32/413 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- METTL3 | c.223G>C p.D75H | Missense Mutation (SNP) | VAF 20/576 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.093); called by muse, mutect2
- MLXIP | c.1535A>G p.H512R | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO7B | c.4226C>G p.S1409C | Missense Mutation (SNP) | VAF 48/791 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NMNAT2 | c.358C>A p.P120T | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.466); called by muse, mutect2
- OR1C1 | c.382C>T p.H128Y | Missense Mutation (SNP) | VAF 14/340 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.068); called by muse, mutect2
- OR5I1 | c.830C>T p.S277L | Missense Mutation (SNP) | VAF 6/151 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PCDHGB1 | c.982A>G p.N328D | Missense Mutation (SNP) | VAF 22/408 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.281); called by muse, mutect2
- PDGFRL | c.242C>G p.A81G | Missense Mutation (SNP) | VAF 26/574 reads (5%) | SIFT tolerated (0.92); PolyPhen benign (0.01); called by muse, mutect2
- PKHD1L1 | c.2209G>A p.D737N | Missense Mutation (SNP) | VAF 9/201 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.006); called by muse, mutect2
- PODNL1 | c.343T>C p.S115P | Missense Mutation (SNP) | VAF 24/528 reads (5%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.519); called by muse, mutect2
- POU4F3 | c.369C>G p.I123M | Missense Mutation (SNP) | VAF 33/917 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2
- RBBP7 | c.358A>G p.I120V | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- SALL1 | c.391G>C p.V131L | Missense Mutation (SNP) | VAF 30/1090 reads (3%) | SIFT tolerated (0.33); PolyPhen benign (0.01); called by muse, mutect2
- SH3BP4 | c.782C>T p.T261I | Missense Mutation (SNP) | VAF 63/609 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SMTNL2 | c.934G>A p.A312T (on ENST00000389313 / NM_001114974.2; = p.A168T on NM_198501.3) | Missense Mutation (SNP) | VAF 124/605 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- ST7 | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 25/464 reads (5%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2
- STYK1 | c.1142A>G p.E381G | Missense Mutation (SNP) | VAF 29/711 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.366); called by muse, mutect2
- SULF2 | c.1723G>T p.D575Y | Missense Mutation (SNP) | VAF 81/785 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- TBC1D30 | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2
- TICRR | c.3191C>G p.S1064C | Missense Mutation (SNP) | VAF 8/220 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- TPP2 | c.1012T>C p.S338P | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- TTLL12 | c.1298A>G p.K433R | Missense Mutation (SNP) | VAF 27/409 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2
- TWNK | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 44/756 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2
- VCAN | c.968G>C p.R323T | Missense Mutation (SNP) | VAF 13/172 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- VPS13C | c.1311T>A p.D437E (on ENST00000644861 / NM_020821.3; = p.D394E on NM_017684.5) | Missense Mutation (SNP) | VAF 29/367 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF641 | c.311G>A p.G104E | Missense Mutation (SNP) | VAF 26/504 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF843 | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 20/447 reads (4%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.138); called by muse, mutect2
- AKAP13 | c.1668T>C p.S556= | Silent (SNP) | VAF 34/394 reads (9%) | called by muse, mutect2
- ANKEF1 | c.87G>A p.E29= | Silent (SNP) | VAF 8/166 reads (5%) | catalogued as COSV65691945; called by muse, mutect2
- APOBR | c.1515T>A p.A505= (on ENST00000431282; = p.A514= on NM_018690.4) | Silent (SNP) | VAF 7/54 reads (13%) | called by muse, mutect2, varscan2
- BBS4 | c.1422A>C p.S474= | Silent (SNP) | VAF 45/912 reads (5%) | called by muse, mutect2
- CNPY4 | c.456C>G p.L152= | Silent (SNP) | VAF 9/156 reads (6%) | called by muse, mutect2
- CYP26A1 | c.990G>A p.L330= | Silent (SNP) | VAF 9/199 reads (5%) | called by muse, mutect2
- DISP3 | c.2532C>G p.V844= | Silent (SNP) | VAF 14/334 reads (4%) | called by muse, mutect2
- DYNC2I1 | c.1236A>G p.Q412= | Silent (SNP) | VAF 29/296 reads (10%) | catalogued as COSV104434672; called by muse, mutect2
- ENTPD5 | c.825A>G p.R275= | Silent (SNP) | VAF 42/534 reads (8%) | called by muse, mutect2
- GBF1 | c.2268G>C p.V756= (on ENST00000369983 / NM_001377137.1; = p.V755= on NM_004193.3) | Silent (SNP) | VAF 32/642 reads (5%) | called by muse, mutect2
- GIMAP7 | c.639G>A p.L213= | Silent (SNP) | VAF 24/502 reads (5%) | called by muse, mutect2
- GLT8D1 | c.615T>G p.T205= | Silent (SNP) | VAF 20/202 reads (10%) | called by muse, mutect2
- GRM7 | c.570G>C p.R190= | Silent (SNP) | VAF 25/616 reads (4%) | called by muse, mutect2
- HRNR | c.2025C>T p.Y675= | Silent (SNP) | VAF 80/1326 reads (6%) | catalogued as rs770212794, COSV100913700; called by muse, mutect2
- HYDIN | c.10050C>T p.H3350= | Silent (SNP) | VAF 44/670 reads (7%) | called by muse, mutect2
- IER3IP1 | c.57C>T p.I19= | Silent (SNP) | VAF 48/1016 reads (5%) | catalogued as rs964329991, COSV56506297; called by muse, mutect2
- IGKV3D-7 | c.90T>C p.S30= | Silent (SNP) | VAF 20/764 reads (3%) | called by muse, mutect2
- ISL2 | c.207C>T p.F69= | Silent (SNP) | VAF 23/361 reads (6%) | catalogued as rs1295921017; called by muse, mutect2
- KIAA1755 | c.172C>T p.L58= | Silent (SNP) | VAF 24/682 reads (4%) | catalogued as COSV54075273; called by muse, mutect2
- MCTP1 | c.609C>G p.G203= | Silent (SNP) | VAF 5/73 reads (7%) | called by muse, mutect2
- NLGN1 | c.642A>T p.V214= | Silent (SNP) | VAF 14/380 reads (4%) | called by muse, mutect2
- OR1N1 | c.537C>T p.I179= | Silent (SNP) | VAF 24/476 reads (5%) | called by muse, mutect2
- OR5V1 | c.558C>A p.I186= | Silent (SNP) | VAF 10/226 reads (4%) | called by muse, mutect2
- PCDHB3 | c.2238C>A p.S746= | Silent (SNP) | VAF 45/531 reads (8%) | called by muse, mutect2, varscan2
- PRSS48 | c.387C>T p.A129= | Silent (SNP) | VAF 51/757 reads (7%) | called by muse, mutect2
- SELENOW | c.9C>T p.L3= | Silent (SNP) | VAF 30/454 reads (7%) | catalogued as rs1410918395; called by muse, mutect2
- SPAG16 | c.1278C>T p.G426= | Silent (SNP) | VAF 33/336 reads (10%) | catalogued as rs1442895165; called by muse, mutect2, varscan2
- TANK | c.1227C>T p.S409= | Silent (SNP) | VAF 16/252 reads (6%) | called by muse, mutect2
- TFB2M | c.759C>A p.I253= | Silent (SNP) | VAF 8/153 reads (5%) | catalogued as COSV100830433; called by muse, mutect2
- TMPRSS6 | c.843C>T p.Y281= | Silent (SNP) | VAF 34/440 reads (8%) | catalogued as rs529404608; called by muse, mutect2
- TRPV1 | c.2487C>A p.V829= | Silent (SNP) | VAF 26/355 reads (7%) | called by muse, mutect2
- TRRAP | c.8568C>G p.A2856= (on ENST00000359863 / NM_001244580.1; = p.A2838= on NM_003496.3) | Silent (SNP) | VAF 70/818 reads (9%) | called by muse, mutect2
- WFIKKN1 | c.1446G>C p.L482= | Silent (SNP) | VAF 44/1052 reads (4%) | called by muse, mutect2
- ZCCHC12 | c.813C>T p.D271= | Silent (SNP) | VAF 12/118 reads (10%) | catalogued as rs1174068367, COSV59571255, COSV59572524; called by muse, mutect2, varscan2
- ZNF618 | c.1848G>A p.V616= (on ENST00000374126 / NM_001318042.2; = p.V523= on NM_133374.2) | Silent (SNP) | VAF 38/590 reads (6%) | catalogued as rs1268649481; called by muse, mutect2
- ABCC13 | n.390G>C | RNA (SNP) | VAF 8/142 reads (6%) | called by muse, mutect2
- ATR | c.7761+82C>G | Intron (SNP) | VAF 7/129 reads (5%) | called by muse, mutect2
- DPP9 | c.1945-35C>T | Intron (SNP) | VAF 12/304 reads (4%) | called by muse, mutect2
- ECM2 | chr9:92494130 G>A | 3'Flank (SNP) | VAF 14/222 reads (6%) | called by muse, mutect2
- KIF13A | c.220+12C>A | Intron (SNP) | VAF 7/130 reads (5%) | called by muse, mutect2
- MYO7A | c.6354+75A>T | Intron (SNP) | VAF 34/569 reads (6%) | called by muse, mutect2
- NBPF11 | c.-549+2240C>T | Intron (SNP) | VAF 64/994 reads (6%) | catalogued as rs1485184744; called by muse, mutect2
- NKX2-1 | c.*31T>A | 3'UTR (SNP) | VAF 22/600 reads (4%) | called by muse, mutect2
- OR6W1P | n.399C>T | RNA (SNP) | VAF 30/319 reads (9%) | catalogued as rs749845816; called by muse, mutect2
- PDE2A | c.704-77A>G | Intron (SNP) | VAF 22/803 reads (3%) | called by muse, mutect2
- SEPTIN6 | c.1281-17_1281-16del | Intron (DEL) | VAF 26/182 reads (14%) | called by pindel, varscan2
- TUBB4AP1 | n.557C>T | RNA (SNP) | VAF 18/304 reads (6%) | called by muse, mutect2
- ZNF347 | c.-26G>A | 5'UTR (SNP) | VAF 12/195 reads (6%) | called by muse, mutect2
